Somatic mutation profile of tumor specimen TCGA-CR-6480-01A (aliquot TCGA-CR-6480-01A-11D-1870-08) from TCGA case TCGA-CR-6480, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 53.3 years (19,472 days).
Specimen TCGA-CR-6480-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e37d517d-156f-4669-b5ec-bfc0ecfce8e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6480-10A (Blood Derived Normal), aliquot TCGA-CR-6480-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac613b25-90c9-4cca-aec6-3e59f38fc663

The open-access MAF lists 110 somatic variants for this specimen: 77 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 31, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV99469174; called by muse, mutect2, varscan2
- ACTB | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100079885; called by muse, mutect2, varscan2
- AGO4 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.621); catalogued as COSV100943045; called by muse, mutect2, varscan2
- ANK3 | c.12236G>C p.R4079T | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.156); catalogued as COSV99781711; called by muse, mutect2, varscan2
- ANK3 | c.11350G>C p.D3784H | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV99781713; called by muse, mutect2, varscan2
- ANK3 | c.11199G>A p.M3733I | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99781715; called by muse, mutect2, varscan2
- ANK3 | c.10405G>A p.E3469K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55048458; called by muse, mutect2, varscan2
- ANK3 | c.9157G>C p.E3053Q | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV99781717; called by muse, mutect2, varscan2
- ANK3 | c.8857G>A p.E2953K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs370916329, COSV99782929; called by muse, varscan2
- ANK3 | c.8809G>A p.E2937K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV55066722; called by muse, varscan2
- ANK3 | c.8686G>A p.E2896K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV55073735; called by muse, mutect2, varscan2
- ANO2 | c.52C>T p.Q18* (on ENST00000356134 / NM_001278597.3; = p.Q22* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100501955; called by muse, mutect2, varscan2
- ARMH3 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100228956; called by muse, mutect2, varscan2
- ATXN7L2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100881360; called by muse, mutect2, varscan2
- B2M | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV62562849, COSV62563168, COSV62564729; called by muse, mutect2, varscan2
- CAMSAP3 | c.2387G>A p.R796K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99351752; called by muse, mutect2
- CCDC191 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs765670138, COSV99878126; called by muse, mutect2, varscan2
- CELSR1 | c.7153C>G p.P2385A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99419584; called by muse, mutect2, varscan2
- CHM | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as CM147109, COSV100753567; called by muse, mutect2, varscan2
- COX17 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99660442; called by muse, mutect2
- CRELD2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV60304271; called by muse, varscan2
- DCDC1 | c.1779G>C p.L593F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1171706521, COSV100664012; called by muse, mutect2, varscan2
- DDX60L | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99488158; called by muse, varscan2
- DENND2A | c.1755A>T p.E585D | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99326781; called by muse, mutect2, varscan2
- DMAC2L | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201122682, COSV99816534; called by muse, mutect2, varscan2
- DMXL1 | c.7624G>A p.E2542K | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs1188078483, COSV100224673; called by muse, mutect2, varscan2
- ERICH3 | c.4316G>A p.R1439Q | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV58602391; called by muse, mutect2
- EZH1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs751414770, COSV70551156; called by muse, mutect2, varscan2
- FBN1 | c.5849C>G p.T1950R | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV100356117; called by muse, mutect2, varscan2
- FGF19 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99594422; called by muse, mutect2
- FOXM1 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.448); catalogued as rs1442499197, COSV100700892; called by muse, mutect2, varscan2
- FRAS1 | c.8578G>A p.E2860K | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1380284315, COSV99355006; called by muse, mutect2, varscan2
- GALNT17 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61170392; called by muse, mutect2, varscan2
- GALR2 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100135606; called by muse, mutect2, varscan2
- HBP1 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV99753507; called by muse, mutect2, varscan2
- HERC1 | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101496807; called by muse, mutect2, varscan2
- IL12RB2 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99255544; called by muse, mutect2, varscan2
- KALRN | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53761123; called by muse, varscan2
- KIF26B | c.4049C>G p.S1350C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100833154; called by muse, mutect2, varscan2
- KIF5C | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101276187; called by muse, mutect2, varscan2
- KRTAP27-1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV101239759; called by muse, mutect2, varscan2
- LIFR | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs763060076, COSV99665147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMLN | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100218798; called by muse, mutect2, varscan2
- LRRC3 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs761564942, COSV99381830; called by muse, mutect2, varscan2
- MARCHF7 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99374017; called by muse, mutect2, varscan2
- MVB12B | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.294); catalogued as COSV100753092; called by muse, mutect2, varscan2
- NAPEPLD | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58523263; called by muse, mutect2, varscan2
- NFATC1 | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as COSV99502310; called by muse, mutect2, varscan2
- NHLRC1 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100513538; called by muse, mutect2, varscan2
- NOL4L | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); catalogued as rs1434322081, COSV100394022; called by muse, mutect2, varscan2
- NRCAM | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs954191486, COSV100695855, COSV61053327; called by muse, mutect2, varscan2
- PAX2 | c.868G>A p.E290K (on ENST00000428433 / NM_003987.5; = p.E267K on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); catalogued as COSV100695368; called by muse, mutect2, varscan2
- PCDHA11 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs971082881, COSV100253228; called by muse, mutect2, varscan2
- PEX5L | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs777000912, COSV99029030, COSV99829602; called by muse, mutect2
- POLD3 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738295; called by muse, mutect2, varscan2
- POT1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as CM1412278, COSV100714126; called by muse, mutect2, varscan2
- PPIL2 | c.1445A>T p.K482M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256434; called by muse, mutect2, varscan2
- PTAR1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as COSV100466687, COSV61208939; called by muse, mutect2, varscan2
- PTPRD | c.3299C>T p.T1100M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs200684369, COSV61937413, COSV61956848; called by muse, mutect2, varscan2
- RECK | c.2189A>G p.E730G | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV100937595; called by muse, mutect2
- RPE | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); catalogued as COSV99780586; called by muse, mutect2, varscan2
- RRP15 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100860789; called by muse, mutect2, varscan2
- RUNX1T1 | c.263A>G p.N88S (on ENST00000265814 / NM_001198628.1; = p.N61S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs1196738917, COSV99754148; called by muse, mutect2
- RYR2 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1271333166, COSV63686700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD5 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV100201002; called by muse, mutect2, varscan2
- SHTN1 | c.1679C>A p.P560H (on ENST00000355371 / NM_001127211.3; = p.S455= on NM_018330.7) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV99599327; called by muse, mutect2, varscan2
- SLX4 | c.4222C>T p.Q1408* | Nonsense Mutation (SNP) | VAF 54/121 reads (45%) | catalogued as COSV99568403; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | PolyPhen benign (0.269); catalogued as COSV99336600; called by muse, mutect2, varscan2
- TAS2R31 | c.562T>A p.F188I | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV101115369; called by muse, varscan2
- TMEM222 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV65027666; called by muse, mutect2, varscan2
- TPR | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as COSV100824195, COSV66601144; called by muse, mutect2, varscan2
- UNC5D | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99777872; called by muse, mutect2, varscan2
- VSIG10 | c.1505G>C p.R502T | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100821338, COSV99075647; called by muse, mutect2, varscan2
- WDR82 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99627174; called by muse, mutect2, varscan2
- ANKRD13A | c.868_874del p.K290Dfs*51 | Frame Shift Del (DEL) | VAF 17/101 reads (17%) | called by mutect2, pindel, varscan2
- ARID5A | c.256_259+1del | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- SLC1A5 | c.833del p.P278Lfs*64 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- APOA5 | c.399G>A p.T133= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as COSV57063104; called by muse, mutect2, varscan2
- CCDC42 | c.531G>T p.T177= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99549814, COSV99549894; called by muse, mutect2, varscan2
- CDKN1B | c.333G>A p.G111= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99964037; called by muse, mutect2, varscan2
- COL5A1 | c.5445C>T p.I1815= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100880402; called by muse, mutect2, varscan2
- CTSS | c.576C>T p.I192= | Silent (SNP) | VAF 54/158 reads (34%) | catalogued as COSV100935010; called by muse, varscan2
- DDX60L | c.429G>A p.L143= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99488156; called by muse, mutect2, varscan2
- DNAJA1 | c.432A>G p.K144= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100438602; called by mutect2, varscan2
- DOK1 | c.1260C>A p.L420= | Silent (SNP) | VAF 91/264 reads (34%) | catalogued as COSV99284168; called by muse, mutect2, varscan2
- DST | c.3201C>G p.L1067= (on ENST00000361203 / NM_001374722.1; = p.L741= on NM_001723.6) | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99758971; called by muse, mutect2, varscan2
- GFRA3 | c.357C>T p.T119= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs530859914, COSV99218524; called by muse, mutect2, varscan2
- ICA1 | c.744T>A p.T248= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV99655711; called by muse, mutect2
- KIAA2026 | c.2025C>T p.L675= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV101199174; called by muse, mutect2, varscan2
- LCTL | c.447C>T p.P149= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100427287; called by muse, mutect2, varscan2
- NCK2 | c.801A>G p.P267= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99256661; called by muse, mutect2, varscan2
- NT5C1B | c.1065C>T p.F355= (on ENST00000359846 / NM_001199086.2; = p.F295= on NM_033253.4) | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV58394300; called by muse, mutect2, varscan2
- PCDH7 | c.309C>T p.F103= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1256450759, COSV100688568; called by muse, mutect2, varscan2
- PDE11A | c.1866C>T p.A622= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV99614225; called by muse, mutect2, varscan2
- PGK1 | c.1155G>T p.T385= | Silent (SNP) | VAF 51/75 reads (68%) | catalogued as COSV100540749, COSV100540771; called by muse, mutect2, varscan2
- PLCB3 | c.426C>T p.I142= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs748738042, COSV99657665; called by muse, varscan2
- PLEC | c.12196C>T p.L4066= (on ENST00000322810 / NM_201380.4; = p.L3956= on NM_000445.5) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1554673772, COSV100517723; called by muse, mutect2, varscan2
- PRPF8 | c.1368G>A p.L456= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV100518057, COSV59267907; called by muse, mutect2, varscan2
- RASAL2 | c.2871G>A p.E957= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100862804; called by muse, mutect2, varscan2
- SEMA5B | c.3342C>T p.F1114= | Silent (SNP) | VAF 45/197 reads (23%) | catalogued as COSV99532914; called by muse, mutect2, varscan2
- SLC35B3 | c.630G>A p.L210= | Silent (SNP) | VAF 45/172 reads (26%) | catalogued as COSV100217392; called by muse, mutect2, varscan2
- SLTM | c.3024A>G p.V1008= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100998827; called by muse, mutect2, varscan2
- TMEM63A | c.1740C>G p.L580= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1205252104, COSV100834435; called by muse, mutect2, varscan2
- TP53I3 | c.798G>A p.L266= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV51979943, COSV99272950; called by muse, mutect2, varscan2
- YPEL1 | c.225C>T p.A75= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs774758879, COSV58604592; called by muse, mutect2, varscan2
- ZNF331 | c.1119C>T p.H373= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs373832810; called by muse, mutect2, varscan2
- ZNF337 | c.915C>G p.S305= | Silent (SNP) | VAF 86/229 reads (38%) | catalogued as COSV99430379; called by muse, mutect2, varscan2
- ZNF512B | c.216G>A p.K72= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV99411748, COSV99412594; called by muse, mutect2, varscan2
- TTN | c.34264+5507C>T | Intron (SNP) | VAF 9/70 reads (13%) | catalogued as rs1437532734, COSV100625159; called by muse, mutect2, varscan2
- TTN | c.34264+5506C>A | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as rs879247400, COSV100625160, COSV60124215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
